CPTAC case C383391 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/d8c7cd89-9716-4137-a564-7013a86f7b91

Demographics
Sex at birth: male; Age at index: 65 years; Vital status: Dead; Days to death: 519 days (1.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Temporal lobe; Site of resection or biopsy: Temporal lobe; Tumor grade: G3; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 519 days (1.4 years); Progression or recurrence: yes; Days to recurrence: 305 days; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Pack years smoked: 15; Cigarettes per day: 10; Alcohol history: Yes.

Biospecimens (9 samples)
- Samples 1104799, 1104800, 1105264, 1105265, SM-JU32R (5 with the same recorded description): Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
- Samples 1104809, 1105202, SM-JU355 (3 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 1105272: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
